Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2R, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2R-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

Liver, segment V and VI, excision: Invasive grade 3 (of 4) adenocarcinoma, consistent with cholangiocarcinoma, forming a 4.8 x 3.1 x 3.0 cm mass with extensive necrosis. Surgical resection margins, including the retroperitoneal margin, are negative for malignancy (free by 0.7 cm).

Gallbladder, cholecystectomy: Chronic cholecystitis and cholesterosis. No stones are identified.

ICD-O-3

Cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

12/3/14

Source: NCI Genomic Data Commons file bfd6367f-97c7-4674-9240-e8481a6296a3 (TCGA-W5-AA2R.153949E2-169E-4138-8D39-9EC9C61C7F3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).